Gene-level copy-number profile of tumor specimen TCGA-25-2397-01A from TCGA case TCGA-25-2397, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 59.1 years (21,581 days).
Specimen TCGA-25-2397-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a01002c1-8053-41b0-b055-ce45f4091349.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-2397-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9d4a407a-875e-402f-b255-ecfac0fab954

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 16,272; copy number 2: 34,127; copy number 3: 7,227; copy number 4: 1,755; copy number 5: 47; copy number 6: 227; copy number 7: 109; copy number 9: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-2397-01A-01D-0704-01): tumor purity 0.91, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 385 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:13,266,542–13,328,583, 1 gene, copy number 9 (within-gene range 3–9): TBC1D7.
- chr6:13,357,830–13,632,739, 7 genes, copy number 5–9 (within-gene range 3–9): GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7.
- chr8:104,330,324–137,092,183, 377 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,666. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
